Surgical pathology report (de-identified scan), TCGA case TCGA-BF-AAOX, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-AAOX-01A (Primary Tumor).

Case #

Patient: **Age (years):** **Gender:** Male

Clinical diagnosis: Melanoma

Date of procurement:

Sample:

Gross description:

The material presented – skin from right hand, pigmented, surgical resection

Microscopic description:

Received material is melanoma mushroom shaped epithelioid melanoma with ulceration, Clark-IV, Breslow - 11 mm, Stage IIC, T4, N0, M0

Final diagnosis: Epithelioid Melanoma

ICD-O-3

Melanoma, epithelioid cell

8771/3

Site: Skin y hand

C44.6

✓ 4/22/14

Confidential

Pw TSS - non-glabrous

Reviewer Initials	Date Re-reviewed	

Source: NCI Genomic Data Commons file d4dac836-f1b3-4947-8421-f84d49668dd1 (TCGA-BF-AAOX.FF31BD7E-A8BE-4362-A25E-861038A556EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).